Gene-level copy-number profile of tumor specimen C3N-00217-02 (profiled together with C3N-00217-04) from CPTAC case C3N-00217, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 59.8 years (21,854 days).
Specimen C3N-00217-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a610ad2-4e4b-4d4b-890e-7caafa9a8e82.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00217-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/a29ac199-37b6-49f8-852f-64bcdf18274b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 172; copy number 2: 10,426; copy number 3: 10,690; copy number 4: 23,980; copy number 5: 6,262; copy number 6: 5,067; copy number 7: 1,041; copy number 8: 391; copy number 9: 111; copy number 10: 111; copy number 11: 31; copy number 20: 3; copy number 22: 10; copy number 31: 48; copy number 46: 1; copy number 52: 11; copy number 94: 31.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:13,844,101–13,849,109, 1 gene: AC022690.2.
- chr14:27,258,717–27,845,286, 3 genes: AL390334.1, LINC00645, MIR3171.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 357 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,676,851–150,353,233, 38 genes, copy number 9–10 (within-gene range 7–10): AC243772.3, RNU1-68P, AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3.
- chr1:150,600,851–152,196,699, 92 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr1:196,774,813–196,795,407, 1 gene, copy number 10: CFHR3.
- chr6:31,164,337–31,862,905, 91 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:35,862,123–40,520,158, 104 genes, copy number 11–52 (broad region; genes not listed).
- chr11:68,870,664–69,926,813, 31 genes, copy number 94: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.

Autosomal genes at a single copy (total copy number 1): 172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
